Gene-level copy-number profile of tumor specimen TCGA-IG-A4P3-01A from TCGA case TCGA-IG-A4P3, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 48.9 years (17,860 days).
Specimen TCGA-IG-A4P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d7b8bb41-5556-413b-b9b9-528960b6100d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A4P3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91a36900-c2d8-403a-8518-007c32e1d836

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 323; copy number 2: 10,767; copy number 3: 12,058; copy number 4: 25,688; copy number 5: 2,425; copy number 6: 5,001; copy number 7: 257; copy number 8: 903; copy number 9: 543; copy number 11: 1,651; copy number 12: 28; copy number 16: 31; copy number 17: 17; copy number 22: 74; copy number 31: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A4P3-01A-11D-A25X-01): tumor purity 0.48, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,586,626–141,167,357, 5 genes: MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,381 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–240,475,187, 36 genes, copy number 9: AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1.
- chr3:93,843,764–115,564,389, 307 genes, copy number 9–11 (broad region; genes not listed).
- chr3:117,672,154–198,222,513, 1,477 genes, copy number 9–17 (broad region; genes not listed).
- chr8:36,121,398–43,674,591, 186 genes, copy number 11–22 (broad region; genes not listed).
- chr11:69,294,151–73,142,318, 132 genes, copy number 9–31 (within-gene range 4–31) (broad region; genes not listed).
- chr17:73,334,384–78,347,798, 215 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:23,197,144–23,437,961, 1 gene, copy number 12 (within-gene range 4–12): TMEM241.
- chr18:23,453,287–24,402,714, 26 genes, copy number 12: RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2.
- chr18:24,429,505–24,429,609, 1 gene, copy number 12: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
